Somatic mutation profile of tumor specimen HTMCP-03-06-02416-01A (aliquot HTMCP-03-06-02416-01A-01D-10409) from CGCI case HTMCP-03-06-02416, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abcbfdc6-7012-4f48-b752-580143de5426.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02416-10A (Blood Derived Normal), aliquot HTMCP-03-06-02416-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f694202-04d6-4fdf-9ad4-45865eccea66

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Frame Shift Ins 3, Intron 2, Splice Site 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.179T>A p.M60K | Missense Mutation (SNP) | VAF 40/72 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV57247351, COSV57256248; called by muse, mutect2, varscan2
- ABCB4 | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395045331, CM084927, COSV55938085; called by muse, mutect2, varscan2
- AK9 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374987709; called by mutect2, varscan2
- CACNA2D2 | c.2901C>A p.F967L (on ENST00000479441 / NM_001174051.3; = p.F960L on NM_006030.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV56560240; called by muse, mutect2, varscan2
- DCAF8L2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs776893287, COSV70552423, COSV70553189; called by muse, mutect2, varscan2
- ERICH3 | c.4463C>T p.P1488L | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV58601486; called by muse, mutect2, varscan2
- FBXO40 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as rs777550766; called by muse, mutect2, varscan2
- GJC1 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs368509499; called by muse, mutect2, varscan2
- GOLGA5 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1228295574; called by muse, mutect2, varscan2
- MAP3K4 | c.2242G>A p.G748R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100815688; called by muse, mutect2, varscan2
- PTPRQ | c.1705G>A p.E569K (on ENST00000616559; = p.E527K on NM_001145026.2) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV99884301; called by muse, mutect2, varscan2
- SOX5 | c.1193C>A p.S398* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100507043; called by muse, mutect2, varscan2
- TTLL8 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.721); catalogued as rs367974537; called by muse, mutect2, varscan2
- ARFGEF3 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 103/144 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATM | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- BTBD8 | c.4765C>T p.H1589Y (on ENST00000636805 / NM_001376131.1; = p.H1076Y on NM_015237.4) | Missense Mutation (SNP) | VAF 163/254 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CHL1 | c.1931-1G>A p.X644_splice (on ENST00000397491 / NM_001253387.1; = p.X660_splice on NM_006614.4) | Splice Site (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- FREM3 | c.4696G>C p.D1566H | Missense Mutation (SNP) | VAF 130/208 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FREM3 | c.4644G>C p.Q1548H | Missense Mutation (SNP) | VAF 138/206 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); called by muse, varscan2
- GRB14 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ITGA8 | c.1540_1546dup p.A516Dfs*41 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- OFD1 | c.2644dup p.I882Nfs*19 | Frame Shift Ins (INS) | VAF 13/126 reads (10%) | called by mutect2, pindel, varscan2
- PLCL2 | c.2794G>T p.D932Y (on ENST00000615277 / NM_001144382.2; = p.D806Y on NM_015184.5) | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLXNB3 | c.1916G>T p.S639I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK11 | c.193dup p.E65Gfs*98 | Frame Shift Ins (INS) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- TYK2 | c.2825C>T p.S942L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- USP47 | c.2350G>A p.E784K (on ENST00000399455 / NM_001372095.1; = p.E696K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- VMP1 | c.1107A>T p.E369D | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- WDR44 | c.2630T>C p.L877S | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR6 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF98 | c.581T>A p.L194H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by mutect2, varscan2
- ABCB5 | c.2076G>A p.V692= (on ENST00000404938 / NM_001163941.2; = p.V247= on NM_178559.6) | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs774692336; called by muse, mutect2, varscan2
- AFF4 | c.972G>A p.T324= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs939378259, COSV54797178; called by muse, mutect2, varscan2
- DACH1 | c.825C>T p.L275= | Silent (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- FOXG1 | c.1146C>T p.A382= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs772266402, COSV57395750; called by mutect2, varscan2
- FRMPD2 | c.3753T>C p.H1251= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs1418493042; called by mutect2, varscan2
- IGSF1 | c.2670T>C p.S890= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- MAP3K19 | c.2502C>T p.L834= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as rs746081479, COSV59639631; called by muse, mutect2, varscan2
- NCOR1 | c.1926A>G p.E642= | Silent (SNP) | VAF 94/157 reads (60%) | called by muse, mutect2, varscan2
- PRR12 | c.1311G>A p.L437= (on ENST00000615927; = p.L1258= on NM_020719.3) | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, varscan2
- RNF213 | c.7131C>G p.L2377= | Silent (SNP) | VAF 79/174 reads (45%) | called by muse, mutect2, varscan2
- SOS2 | c.2211G>A p.R737= | Silent (SNP) | VAF 114/232 reads (49%) | called by muse, mutect2, varscan2
- TMC4 | c.954C>T p.Y318= (on ENST00000617472 / NM_001145303.3; = p.Y312= on NM_144686.4) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV56600898; called by muse, mutect2, varscan2
- UNC13C | c.5070A>G p.E1690= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- SERPINA3 | c.-63C>G | 5'UTR (SNP) | VAF 62/133 reads (47%) | catalogued as rs772375201; called by muse, mutect2, varscan2
- SLIT2 | c.179+1023G>A | Intron (SNP) | VAF 7/9 reads (78%) | catalogued as rs1301806227; called by muse, mutect2, varscan2
- TTN | c.33340+384G>A | Intron (SNP) | VAF 8/36 reads (22%) | catalogued as rs894171947, COSV60086368; called by muse, mutect2, varscan2
